Gene-level copy-number profile of tumor specimen ALCH-B40Q-TTP1-A from ALCHEMIST case ALCH-B40Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.2 years (19,447 days).
Specimen ALCH-B40Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 26995d2d-a29e-4cf1-b72c-510add13fe37.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/473b9b70-b065-4609-8f57-bf9683a55eaa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 12,672; copy number 2: 42,772; copy number 3: 2,226; copy number 4: 426; copy number 5: 68; copy number 6: 202; copy number 7: 2; copy number 10: 2; copy number 22: 3.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr6:149,998,019–150,005,157, 1 gene: RAET1K.
- chr7:44,962,662–44,979,088, 1 gene: MYO1G.
- chr13:99,173,593–99,200,757, 3 genes: RPS6P23, UBAC2-AS1, GAPDHP22.
- chr13:99,205,708–99,215,758, 2 genes (within-gene range 0–1): RN7SKP9, H2AZP3.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:105,597,691–105,601,728, 1 gene: IGHE.
- chr15:50,424,380–50,689,193, 8 genes: USP8, RNA5SP395, AC012170.1, USP50, TRPM7, AC084756.1, AC084756.2, RN7SL354P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 277 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,345,099, 48 genes, copy number 6: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:161,751,448–162,162,977, 4 genes, copy number 5: GLRXP3, GABRA1, LINC01202, GABRG2.
- chr5:170,105,897–177,022,633, 153 genes, copy number 6 (broad region; genes not listed).
- chr5:179,550,554–181,061,521, 62 genes, copy number 5 (broad region; genes not listed).
- chr21:43,446,601–43,479,534, 3 genes, copy number 10–22: LINC00319, LINC00313, AP001048.1.
- chr22:18,846,811–18,894,407, 4 genes, copy number 5–7 (within-gene range 5–11): AC008132.1, BCRP7, FAM230F, AC008103.1.
- chr22:18,906,238–18,947,741, 3 genes, copy number 6–22 (within-gene range 1–22): AC007326.4, PRODH, AC007326.5.

Autosomal genes at a single copy (total copy number 1): 12,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
